Gene-level copy-number profile of tumor specimen TCGA-GU-A762-01A from TCGA case TCGA-GU-A762, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 87.1 years (31,812 days).
Specimen TCGA-GU-A762-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.9812bc8c-34ec-423c-8625-92373174b5ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GU-A762-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a8d03c7b-99c4-40cd-804b-e4dbf162ca51

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 36; copy number 2: 16,755; copy number 3: 7,871; copy number 4: 26,343; copy number 5: 4,729; copy number 6: 2,423; copy number 7: 338; copy number 8: 129; copy number 9: 968; copy number 10: 148; copy number 11: 54; copy number 14: 7; copy number 38: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GU-A762-01A-11D-A338-01): tumor purity 0.31, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,025,897–246,189,118, 4 genes: AC118555.1, SMYD3-AS1, CHCHD4P5, RNU6-1283P.
- chr6:65,302,522–66,094,909, 4 genes: AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,181 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,688,749–61,462,788, 118 genes, copy number 10–38 (broad region; genes not listed).
- chr2:212,426,263–213,284,205, 13 genes, copy number 10–11 (within-gene range 3–11): MIR548F2, AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT.
- chr5:14,143,342–45,895,970, 456 genes, copy number 9 (broad region; genes not listed).
- chr6:44,727,921–53,924,125, 149 genes, copy number 9–11 (within-gene range 7–11) (broad region; genes not listed).
- chr11:102,295,060–103,045,712, 29 genes, copy number 9: AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1.
- chr11:103,050,687–103,055,799, 1 gene, copy number 9: AP001486.2.
- chr16:71,623,708–72,225,144, 29 genes, copy number 10: AC009097.2, MARVELD3, PHLPP2, AC009097.1, RNU6-208P, SNORA70D, AC009097.4, AC009097.3, AP1G1, SNORD71, AC010653.3, AC010653.1, ATXN1L, IST1, AC010653.2, ZNF821, AC009127.1, PKD1L3, RPL39P31, AC009127.2, ATP5F1AP3, DHODH, TXNL4B, HP, HPR, AC009087.1, DHX38, PMFBP1, AC009075.1.
- chr18:47,390–15,330,282, 376 genes, copy number 9 (broad region; genes not listed).
- chr18:21,914,369–22,205,229, 10 genes, copy number 11: AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
